Gene-level copy-number profile of tumor specimen TCGA-14-1454-01A from TCGA case TCGA-14-1454, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.4 years (19,887 days).
Specimen TCGA-14-1454-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.f770f31a-f97e-4c83-b7f1-4c055351a82a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-14-1454-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b781d945-399b-4f69-a0cf-165b65ff8414

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 67; copy number 2: 11,061; copy number 3: 31,486; copy number 4: 14,586; copy number 5: 2,604.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-14-1454-01): tumor purity 0.95, ploidy 3.03, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:49,956,670–50,125,720, 1 gene (within-gene range 0–2): DLEU2.
- chr13:50,044,649–50,081,978, 8 genes: AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,361,763, 6 genes: AL137060.6, RPL18P10, AL137060.1, AL137060.3, ST13P4, RPL34P26.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 67. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
